Somatic mutation profile of tumor specimen 0DHY4U from CCDI case PBBUXY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.0 years (5,474 days).
Specimen 0DHY4U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6da0670a-83c6-4df7-83ab-8653d8b9472e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58bf02a7-4733-4401-aff3-f780a743cd74

The open-access MAF lists 5 somatic variants for this specimen: 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/195 reads (5%) | called by muse, mutect2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- LARP4 | c.1334+89G>T | Intron (SNP) | VAF 8/77 reads (10%) | called by mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
